Somatic mutation profile of tumor specimen 0D9HZH from CCDI case PBBIUB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.4 years (495 days).
Specimen 0D9HZH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b0855c5-01c0-45d0-9322-182800b365e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9HZ1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8928994b-98f8-479f-b25a-f512b03dd9b6

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 3, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SDK2 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 31/410 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as rs993460085, COSV66191488; called by muse, mutect2
- CFAP46 | c.662T>C p.V221A | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 22/528 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- TSPY2 | c.77C>A p.A26E | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.097); called by muse, mutect2
- WDR33 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 32/359 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as rs1167537044; called by mutect2, varscan2
- H4C13 | c.*17C>G | 3'UTR (SNP) | VAF 70/184 reads (38%) | called by muse, mutect2, varscan2
- NCF4 | c.529-90G>A | Intron (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- TTC8 | c.459+44T>A | Intron (SNP) | VAF 22/191 reads (12%) | called by muse, varscan2
